Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PO, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PO-01A (Primary Tumor).

ICD O3
Adenocarcinoma, signet ring cell
Site: Gastric antrum 849013
C16.3

W 3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

Product of gastrectomy

Adenocarcinoma:

Histological pattern observed:

Mucosecretor mucocellular with "signet ring" cells

Histological grade:

III - Poorly differentiated.

Lauren's classification: diffuse type

Measure of the longest axis of the tumor: 5.0 cm

Ulceration: present

Involvement of: serosa

Type of tumor invasion: expansive

Inflammatory reaction: moderate

Tumor implantation in perivisceral adipose tissue: absent

Proximal and distal margins: Absence of neoplastic involvement.

Neural infiltration: not detected

Lymphatic vascular invasion: not detected

Blood vascular invasion: not detected

Lesser omentum: absence of neoplastic involvement.

Lesser curvature lymph nodes:

Absence of neoplasia: (0/8)

Greater curvature lymph nodes:

Absence of neoplasia: (0/6)

Lymph nodes of the anterior hepatic artery:

Absence of neoplasia: (0/4)

Lymph nodes of the posterior hepatic artery:

Absence of neoplasia: (0/2)

Lymph nodes of the splenic artery:

Absence of neoplasia: (0/3)

Lymph nodes of the celiac trunk:

Absence of neoplasia: (0/3)

Source: NCI Genomic Data Commons file 4f15394c-af87-4653-96ea-86b46f5e1e46 (TCGA-VQ-A8PO.1328EA37-86D1-45F2-8BD9-BB147A9E8254.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).